Somatic mutation profile of tumor specimen HCM-BROD-1124-C16-06A (aliquot HCM-BROD-1124-C16-06A-01D-A881-36) from HCMI case HCM-BROD-1124-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen HCM-BROD-1124-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fead3160-701d-4be3-a308-3f3d64ffcf57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1124-C16-10A (Blood Derived Normal), aliquot HCM-BROD-1124-C16-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9df6518e-ed3b-46bf-b500-46b09750d95d

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Region 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs1344172059, COSV56859663; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.219); catalogued as rs1363649764, COSV100608968; called by muse, mutect2, varscan2
- CES2 | c.423G>A p.P141= | Splice Region (SNP) | VAF 26/111 reads (23%) | catalogued as rs757492387, COSV57697090; called by muse, varscan2
- COL20A1 | c.2902G>A p.G968R | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753868347; called by muse, mutect2
- DUSP12 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769804396; called by muse, varscan2
- SZT2 | c.9637C>T p.R3213W (on ENST00000634258 / NM_001365999.1; = p.R3156W on NM_015284.4) | Missense Mutation (SNP) | VAF 14/534 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1483282139; called by muse, mutect2
- ACACA | c.3249T>C p.D1083= | Splice Region (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- LCE4A | c.129_134del p.S44_S45del | In Frame Del (DEL) | VAF 7/79 reads (9%) | called by mutect2*, pindel
- PXDN | c.3970C>A p.Q1324K | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.325); called by muse, varscan2
- SFTPA1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, varscan2
- TMEM229A | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZDHHC13 | c.811del p.T271Qfs*5 | Frame Shift Del (DEL) | VAF 40/286 reads (14%) | called by mutect2, pindel, varscan2
- ZNF446 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MUC16 | c.22668C>A p.A7556= | Silent (SNP) | VAF 64/355 reads (18%) | called by muse, varscan2
- SORCS1 | c.1401C>A p.I467= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as COSV53913580; called by muse, mutect2, varscan2
